Gene-level copy-number profile of tumor specimen TCGA-NC-A5HP-01A from TCGA case TCGA-NC-A5HP, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 69.2 years (25,286 days).
Specimen TCGA-NC-A5HP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.ca78ddfc-8cde-4635-8a13-b4f9357594a1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NC-A5HP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/18e724de-f9ce-4eb2-90e8-6d1a071f38d9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 677; copy number 2: 16,943; copy number 3: 12,257; copy number 4: 19,005; copy number 5: 3,829; copy number 6: 2,511; copy number 7: 2,935; copy number 8: 84; copy number 9: 681; copy number 10: 571; copy number 11: 186; copy number 13: 119.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NC-A5HP-01A-11D-A26L-01): tumor purity 0.53, ploidy 3.67, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:30,292,548–31,455,894, 14 genes: AC025614.2, AC025614.1, U3, LINC01985, AC116035.1, TGFBR2, AC096921.1, AC096921.2, GADL1, MIR466, CNN2P6, RNA5SP127, H3P11, THRAP3P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,557 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:95,654,423–95,919,552, 2 genes, copy number 10: MTHFD2P1, AC106719.1.
- chr3:135,925,891–166,721,610, 471 genes, copy number 9–10 (broad region; genes not listed).
- chr3:168,094,049–174,378,005, 100 genes, copy number 11 (broad region; genes not listed).
- chr3:174,631,823–174,632,064, 1 gene, copy number 11: RN7SKP40.
- chr3:175,675,087–186,772,986, 225 genes, copy number 9–11 (within-gene range 7–11) (broad region; genes not listed).
- chr9:26,642,697–38,068,687, 284 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr9:37,885,683–37,886,390, 1 gene, copy number 9: TMX2P1.
- chr14:18,333,726–24,190,416, 435 genes, copy number 10–13 (within-gene range 4–13) (broad region; genes not listed).
- chr15:75,336,020–76,059,795, 38 genes, copy number 10 (within-gene range 5–10): COMMD4, AC068338.3, NEIL1, MIR631, MAN2C1, AC068338.2, SIN3A, RPL13P4, AC105137.1, AC105137.2, PTPN9, AC105036.2, AC105036.1, AC105036.3, SNUPN, AC105020.3, AC105020.2, IMP3, AC105020.6, AC105020.5, SNX33, CSPG4, AC105020.4, AC105020.1, ODF3L1, DNM1P35, AC019294.2, PPIAP47, AC019294.3, MIR4313, AC019294.1, RN7SL319P, DNM1P49, UBE2Q2, RN7SL510P, FBXO22, NRG4, AC027104.1.

Autosomal genes at a single copy (total copy number 1): 643. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
